Somatic mutation profile of tumor specimen TCGA-BP-5185-01A (aliquot TCGA-BP-5185-01A-01D-1429-08) from TCGA case TCGA-BP-5185, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 56.0 years (20,470 days).
Specimen TCGA-BP-5185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a961d7b4-6320-48a0-a4dc-f4cb23c79521.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5185-11A (Solid Tissue Normal), aliquot TCGA-BP-5185-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe56fde6-d10d-49a5-81e4-6fe992a7f405

The open-access MAF lists 83 somatic variants for this specimen: 70 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 11, Frame Shift Del 9, Splice Site 2, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.350G>A p.W117* | Nonsense Mutation (SNP) | VAF 108/182 reads (59%) | hotspot (GDC flag); catalogued as rs1559428056, CM141838, CM961425, COSV56542825, COSV56544265, COSV56548887; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APBA2 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs751602124, COSV68788501; called by muse, mutect2, varscan2
- ARHGAP20 | c.2063C>A p.T688K | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV52806407; called by muse, mutect2, varscan2
- ARMC4 | c.920A>C p.E307A | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.421); catalogued as COSV53462488; called by muse, mutect2, varscan2
- ATR | c.6961T>A p.F2321I | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.049); catalogued as COSV63383739; called by muse, mutect2, varscan2
- ATXN7L2 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.947); catalogued as rs1244199373, COSV63992050; called by muse, mutect2, varscan2
- AVIL | c.142-2A>G p.X48_splice | Splice Site (SNP) | VAF 56/149 reads (38%) | catalogued as COSV57680297; called by muse, mutect2, varscan2
- CABIN1 | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.703); catalogued as rs1369639475, COSV54077430; called by muse, mutect2, varscan2
- CALU | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV50821220; called by muse, mutect2, varscan2
- CDYL | c.806G>A p.G269D (on ENST00000328908 / NM_001368125.1; = p.G215D on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59358222; called by muse, mutect2, varscan2
- CHI3L1 | c.999C>G p.S333R | Missense Mutation (SNP) | VAF 103/221 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55137045; called by muse, mutect2, varscan2
- CNOT1 | c.2048A>C p.K683T | Missense Mutation (SNP) | VAF 94/182 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV57764442; called by muse, mutect2, varscan2
- DAAM1 | c.2916C>A p.F972L | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV62834094; called by muse, mutect2, varscan2
- DNHD1 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 180/467 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV54430268; called by muse, mutect2, varscan2
- EPHA8 | c.1441-1G>C p.X481_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV51262516; called by muse, mutect2, varscan2
- FAM71C | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60942575; called by muse, mutect2, varscan2
- FBN3 | c.4237C>T p.L1413F | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV54453162; called by muse, mutect2, varscan2
- FEM1C | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57230701; called by muse, mutect2, varscan2
- FOXR1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57651236; called by muse, mutect2
- FOXR1 | c.121A>T p.N41Y | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV57651247; called by muse, mutect2
- FSCN1 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV61016943; called by muse, mutect2, varscan2
- GBF1 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64142697; called by muse, mutect2, varscan2
- HIVEP1 | c.7493T>C p.I2498T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65098542; called by muse, mutect2, varscan2
- HS6ST3 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV65001865; called by muse, mutect2
- INSL6 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV67562502; called by muse, mutect2, varscan2
- KLRC2 | c.520G>C p.G174R | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV67899341; called by muse, mutect2, varscan2
- KRTAP4-12 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.35); catalogued as COSV67457630; called by muse, mutect2, varscan2
- LRP11 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs374603588, COSV53333027; called by muse, mutect2, varscan2
- LRP1B | c.3904C>T p.L1302F | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67185227, COSV67272272; called by muse, mutect2, varscan2
- LVRN | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.145); catalogued as COSV63495894; called by muse, mutect2, varscan2
- MAML1 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV52982803, COSV52982904; called by muse, mutect2, varscan2
- MED13 | c.5246G>C p.R1749T | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV67261850, COSV67266598; called by muse, mutect2, varscan2
- MED18 | c.259T>A p.Y87N | Missense Mutation (SNP) | VAF 132/271 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65790268; called by muse, varscan2
- MYO7A | c.2909T>G p.L970R | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68683348; called by muse, mutect2, varscan2
- NAF1 | c.1463C>A p.S488Y | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV56803188, COSV56805823; called by muse, mutect2, varscan2
- NPHP3 | c.1651T>C p.S551P | Missense Mutation (SNP) | VAF 57/89 reads (64%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as COSV58627874; called by muse, mutect2, varscan2
- NR4A1 | c.39A>C p.E13D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); catalogued as COSV100819800; called by muse, mutect2, varscan2
- OR51L1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58623872, COSV58626040; called by muse, mutect2
- OR51Q1 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1235915674, COSV56177805; called by muse, mutect2, varscan2
- PCDHAC2 | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV53836569, COSV53840745; called by muse, mutect2, varscan2
- PCDHGB7 | c.1443C>G p.F481L | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53896582, COSV53984440; called by muse, mutect2, varscan2
- PCDHGC5 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 105/276 reads (38%) | catalogued as COSV52742931; called by muse, mutect2, varscan2
- PCLO | c.12569A>G p.K4190R | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61615247; called by muse, varscan2
- PKP4 | c.1805C>G p.S602C | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV67675540; called by muse, varscan2
- PPM1B | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56764965, COSV56765756; called by muse, mutect2, varscan2
- QSOX2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as rs376604129; called by muse, mutect2, varscan2
- RELCH | c.3235C>G p.P1079A | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV56881987; called by muse, mutect2, varscan2
- RNF19B | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52386711; called by muse, mutect2, varscan2
- RTF1 | c.980A>G p.K327R | Missense Mutation (SNP) | VAF 184/524 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV67477693; called by muse, mutect2, varscan2
- SCD5 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV51101868; called by muse, mutect2, varscan2
- SNAI3 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60002284; called by muse, mutect2, varscan2
- SOX9 | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as COSV55422224; called by muse, mutect2, varscan2
- SPAG5 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 125/361 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV58799936; called by muse, mutect2, varscan2
- TNFRSF1A | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV50598223; called by muse, mutect2, varscan2
- TTN | c.64307T>A p.L21436H (on ENST00000591111; = p.L14012H on NM_003319.4) | Missense Mutation (SNP) | VAF 68/174 reads (39%) | PolyPhen probably damaging (0.944); catalogued as COSV59880878; called by muse, mutect2, varscan2
- UBAP2L | c.2278A>C p.S760R | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV55167664; called by muse, mutect2, varscan2
- USP40 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs759413224, COSV52477060; called by muse, mutect2, varscan2
- ZC3HAV1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV54293163, COSV99648367; called by muse, mutect2, varscan2
- ZNF687 | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60677897; called by muse, mutect2, varscan2
- ZNF804A | c.935G>C p.C312S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as COSV56435083; called by muse, mutect2, varscan2
- ANKRD12 | c.2777_2778del p.K926Rfs*10 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- ARFIP1 | c.1056del p.K353Nfs*7 (on ENST00000353617 / NM_001287432.1; = p.K321Nfs*7 on NM_014447.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/206 reads (17%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.542_543dup p.E182Mfs*9 | Frame Shift Ins (INS) | VAF 11/86 reads (13%) | called by mutect2, pindel, varscan2
- DENND4A | c.4954_4955del p.E1652Kfs*2 | Frame Shift Del (DEL) | VAF 55/192 reads (29%) | called by mutect2, pindel, varscan2
- FLG | c.1102_1103del p.Q368Dfs*6 | Frame Shift Del (DEL) | VAF 227/609 reads (37%) | called by mutect2, pindel, varscan2
- GAL3ST1 | c.150del p.S51Pfs*12 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- ITIH4 | c.1824del p.M609Wfs*50 | Frame Shift Del (DEL) | VAF 45/97 reads (46%) | called by mutect2, pindel, varscan2
- NUP160 | c.2059del p.M687Wfs*11 | Frame Shift Del (DEL) | VAF 102/363 reads (28%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4782del p.F1594Lfs*2 (on ENST00000296302 / NM_001366071.2; = p.F1487Lfs*2 on NM_018313.5) | Frame Shift Del (DEL) | VAF 50/98 reads (51%) | called by mutect2, pindel, varscan2
- ZBTB43 | c.1030del p.A344Qfs*11 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | called by mutect2, pindel, varscan2
- AGAP1 | c.780G>A p.V260= | Silent (SNP) | VAF 159/432 reads (37%) | catalogued as COSV58317093; called by muse, mutect2, varscan2
- CDK8 | c.216G>A p.E72= | Silent (SNP) | VAF 126/270 reads (47%) | catalogued as COSV67419137; called by muse, varscan2
- CKAP2 | c.840A>T p.T280= (on ENST00000378037 / NM_001098525.2; = p.T279= on NM_018204.5) | Silent (SNP) | VAF 55/106 reads (52%) | catalogued as COSV51620755; called by muse, mutect2, varscan2
- CPA4 | c.129A>T p.L43= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV55982245; called by muse, mutect2, varscan2
- DDX54 | c.279G>A p.K93= | Silent (SNP) | VAF 76/243 reads (31%) | catalogued as COSV58371844; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1434C>T p.D478= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as rs752079647, COSV57514440; called by muse, mutect2, varscan2
- KBTBD6 | c.1890C>T p.L630= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV65270856; called by muse, mutect2
- LRP11 | c.894C>T p.R298= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs775277927, COSV53332903; called by muse, mutect2, varscan2
- PGPEP1L | c.444T>A p.P148= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV51269894; called by muse, mutect2, varscan2
- TTN | c.77910A>G p.E25970= (on ENST00000591111; = p.E18546= on NM_003319.4) | Silent (SNP) | VAF 57/149 reads (38%) | catalogued as COSV59880842; called by muse, mutect2, varscan2
- UNK | c.1497A>C p.A499= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV53139242; called by muse, mutect2, varscan2
- TTN | c.10360+1548A>C | Intron (SNP) | VAF 57/421 reads (14%) | catalogued as COSV59880914; called by muse, mutect2, varscan2
- USH1C | c.1284+7574G>A | Intron (SNP) | VAF 24/69 reads (35%) | catalogued as rs1452856374, COSV50013984; called by muse, mutect2, varscan2
